Somatic mutation profile of tumor specimen MMRF_2410_1_BM_CD138pos (aliquot MMRF_2410_1_BM_CD138pos_T3_KHS5U_K14029) from MMRF case MMRF_2410, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.7 years (22,179 days).
Specimen MMRF_2410_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac31ad9d-7af1-4aae-ab71-e6a6578c09b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2410_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2410_1_PB_Whole_C1_KHS5U_K14028; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41482be1-6cc7-4aa6-9ea3-f6f77b5d011f

The open-access MAF lists 126 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 30, Silent 18, Intron 17, Frame Shift Del 6, Frame Shift Ins 4, Nonsense Mutation 3, 3'Flank 2, 5'UTR 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABCA4 | c.5024C>T p.T1675I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375156009; called by muse, mutect2, varscan2
- BMPER | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs753256351, COSV51826487; called by muse, mutect2, varscan2
- C19orf12 | c.295C>A p.L99I (on ENST00000392278 / NM_001031726.3; = p.L88I on NM_031448.6) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60364457; called by muse, mutect2
- CEP85 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1197265973, COSV53331720; called by muse, mutect2, varscan2
- CHRNA4 | c.1758G>A p.S586= | Splice Region (SNP) | VAF 12/93 reads (13%) | catalogued as rs199662429; called by muse, mutect2, varscan2
- COL6A1 | c.2965G>A p.G989S | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs138652066; called by muse, mutect2, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 15/37 reads (41%) | catalogued as rs752363479; called by mutect2, varscan2
- EPHA7 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65169412; called by muse, mutect2, varscan2
- EVC2 | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs769623217, COSV60393395; called by muse, mutect2
- GALNT10 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/330 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301016919, COSV51734416; called by muse, mutect2
- IGHV2-70 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs544365977; called by muse, mutect2, varscan2
- LAMC3 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533415883; called by muse, mutect2, varscan2
- LRP1 | c.13097C>T p.T4366M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs532522583; called by muse, mutect2, varscan2
- PCDHA1 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100974283; called by muse, mutect2, varscan2
- ROBO3 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as rs1256318810; called by muse, mutect2, varscan2
- SLC40A1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 76/187 reads (41%) | catalogued as COSV104369319; called by muse, mutect2, varscan2
- STK11IP | c.1411C>G p.P471A | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV55250455; called by muse, mutect2, varscan2
- VSIG8 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs767131783; called by muse, mutect2, varscan2
- ZC3HAV1L | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1563116247; called by muse, mutect2, varscan2
- ZNF350 | c.1435C>A p.L479I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV54707863; called by muse, mutect2, varscan2
- ZNF652 | c.1491del p.V498* | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as COSV62946698, COSV62948807; called by mutect2, pindel, varscan2
- AHSG | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.579); called by muse, mutect2
- APLNR | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CCDC150 | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CDH7 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by mutect2, varscan2
- EIF2S2 | c.800_803del p.I267Kfs*4 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, varscan2
- EIF4G2 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2
- ENTPD6 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- FIP1L1 | c.1641_1645dup p.R549Ifs*75 | Frame Shift Ins (INS) | VAF 40/131 reads (31%) | called by mutect2, pindel, varscan2
- GPS2 | c.322del p.L108* | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- IFNAR1 | c.999del p.P334Lfs*28 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- IGHA1 | c.1029_1031del p.V344del | In Frame Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2
- IQCH | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- IRAK1 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGI3 | c.2428A>G p.I810V | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- NKX2-8 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- NOL8 | c.3444C>A p.N1148K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NOLC1 | c.45T>G p.Y15* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- NUDCD1 | c.1370T>C p.L457S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OGDH | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PGAP1 | c.16_19del p.V6Ifs*33 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.392C>G p.S131C (on ENST00000414982 / NM_001166111.2; = p.S83C on NM_006702.5) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPFIA2 | c.2867dup p.L956Ffs*30 | Frame Shift Ins (INS) | VAF 26/118 reads (22%) | called by pindel, varscan2
- PTPRM | c.1653dup p.G552Wfs*15 | Frame Shift Ins (INS) | VAF 31/163 reads (19%) | called by mutect2, pindel, varscan2
- R3HDM4 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RIPOR1 | c.2049del p.T684Lfs*3 (on ENST00000379312 / NM_001193522.2; = p.T680Lfs*3 on NM_024519.4) | Frame Shift Del (DEL) | VAF 43/206 reads (21%) | called by mutect2, pindel, varscan2
- RNF112 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RNF213 | c.10453C>T p.H3485Y | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SCN7A | c.2141T>C p.L714S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SERTAD2 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGS1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TNS1 | c.763T>G p.F255V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TULP4 | c.2349G>C p.M783I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.2887G>T p.G963* | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | called by muse, mutect2, varscan2
- ZNF728 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF91 | c.2515T>C p.S839P | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO3 | c.2839C>A p.R947= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ATCAY | c.708C>T p.N236= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as rs1056783124, COSV56658788, COSV56658976; called by muse, mutect2, varscan2
- CD180 | c.1914T>C p.F638= | Silent (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- FABP7 | c.381C>T p.R127= | Silent (SNP) | VAF 24/509 reads (5%) | called by muse, mutect2
- FAM237A | c.384G>A p.A128= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs376138541, COSV101405557; called by muse, mutect2, varscan2
- IGHV2-70D | c.54A>G p.L18= | Silent (SNP) | VAF 27/35 reads (77%) | called by muse, mutect2, varscan2
- MGAT4C | c.720C>A p.V240= | Silent (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- NDC1 | c.1263T>C p.P421= | Silent (SNP) | VAF 77/182 reads (42%) | called by muse, mutect2, varscan2
- OPN5 | c.105G>T p.V35= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs1368722638; called by muse, mutect2, varscan2
- PLXNA4 | c.912G>A p.G304= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV58150985; called by muse, mutect2, varscan2
- PNPLA6 | c.3558C>G p.P1186= (on ENST00000414982 / NM_001166111.2; = p.P1138= on NM_006702.5) | Silent (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- PTPN23 | c.3507G>A p.E1169= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs1333768953; called by muse, mutect2, varscan2
- RNF157 | c.1740C>A p.L580= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- SLC27A6 | c.444C>T p.I148= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SRRM1 | c.2142G>A p.P714= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as rs1468189906; called by muse, mutect2, varscan2
- UTP3 | c.514C>T p.L172= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- ZBTB38 | c.2589G>T p.G863= | Silent (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- ZNF503 | c.1575C>T p.C525= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs769052845, COSV65307859; called by muse, mutect2
- ANKRD1 | c.*92T>C | 3'UTR (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2
- ATOH7 | c.*63T>C | 3'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2
- B4GALT5 | c.*2942C>G | 3'UTR (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- BEX2 | c.*82G>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- CDKL1 | c.799-183_799-180del | Intron (DEL) | VAF 41/294 reads (14%) | catalogued as rs1197215259; called by pindel, varscan2
- CDX1 | c.*165A>C | 3'UTR (SNP) | VAF 57/103 reads (55%) | called by muse, mutect2, varscan2
- COL28A1 | c.1998+1051T>G | Intron (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- DTWD2 | c.*160_*163del | 3'UTR (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.*111T>C | 3'UTR (SNP) | VAF 48/117 reads (41%) | called by muse, varscan2
- ENTPD1 | c.*162A>G | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, varscan2
- FAM114A2 | c.*1199A>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- FBN1 | c.*1047C>T | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- FBXO43 | c.1674+78G>A | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- FCSK | c.582+133G>T | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs190383706; called by mutect2, varscan2
- GADD45A | c.*387C>T | 3'UTR (SNP) | VAF 5/43 reads (12%) | catalogued as rs972422480; called by muse, mutect2, varscan2
- GCNT1 | c.*1467A>T | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- GNL1 | c.1100-90C>G | Intron (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2
- GPSM3 | c.*232G>A | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- HAO1 | c.*495G>T | 3'UTR (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- HMGA2 | c.*1607C>T | 3'UTR (SNP) | VAF 35/78 reads (45%) | catalogued as rs922962694; called by muse, mutect2, varscan2
- HNRNPL | c.952+9A>G | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs753605911; called by muse, mutect2, varscan2
- IP6K1 | c.*2343C>A | 3'UTR (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2
- IRAK1BP1 | c.*4728A>T | 3'UTR (SNP) | VAF 137/429 reads (32%) | called by muse, mutect2
- KCNMB4 | c.*112C>T | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1471+16327T>G | Intron (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- LGALS9 | c.541-123G>A | Intron (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- MAFK | c.*1419G>A | 3'UTR (SNP) | VAF 62/139 reads (45%) | catalogued as rs190852165; called by muse, mutect2, varscan2
- MEIS3 | c.*356C>T | 3'UTR (SNP) | VAF 92/150 reads (61%) | called by muse, mutect2, varscan2
- MTOR | c.4687-126C>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as rs1358890031; called by muse, mutect2, varscan2
- OLFML2A | c.*4152G>T | 3'UTR (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- OSBPL8 | c.218-12503A>G | Intron (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- PPFIA1 | c.2865+2830C>T | Intron (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- PSMD7 | chr16:74307445 C>A | 3'Flank (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- PYCR3 | c.337-67C>T | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as rs1048747903; called by muse, mutect2, varscan2
- RBM43 | c.*86G>A | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs939787288; called by muse, mutect2, varscan2
- RNF183 | c.-27G>A | 5'UTR (SNP) | VAF 11/62 reads (18%) | catalogued as rs371236275; called by muse, mutect2, varscan2
- SEC31B | c.496-476C>T | Intron (SNP) | VAF 65/144 reads (45%) | catalogued as rs929623121; called by muse, mutect2, varscan2
- SLC35G1 | c.*1411T>A | 3'UTR (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- SP140 | c.2174+124G>T | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- SPN | c.*1140C>T | 3'UTR (SNP) | VAF 31/66 reads (47%) | catalogued as rs1297194793, COSV100788893; called by muse, mutect2, varscan2
- SRD5A1 | c.*746G>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | catalogued as rs777219980; called by muse, mutect2, varscan2
- TMEM273 | c.293+1036dup | Intron (INS) | VAF 5/56 reads (9%) | catalogued as rs1236355406; called by pindel, varscan2
- TPP1 | c.1075+116G>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- TUBA8 | c.227-59G>A | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as rs1336979210; called by muse, mutect2, varscan2
- TXLNB | c.*1780A>G | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- UBE2G2 | c.*432_*436del | 3'UTR (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- UBE2NL | c.*142T>A | 3'UTR (SNP) | VAF 145/154 reads (94%) | called by muse, mutect2, varscan2
- ZFP37 | c.*4173C>A | 3'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- ZMYM2 | chr13:20088009 T>C | 3'Flank (SNP) | VAF 32/40 reads (80%) | catalogued as rs892370216; called by muse, mutect2, varscan2
- ZNF503-AS2 | n.919A>G | RNA (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- ZNF780A | c.*502G>A | 3'UTR (SNP) | VAF 14/84 reads (17%) | catalogued as COSV61814624; called by muse, mutect2, varscan2
